Somatic mutation profile of tumor specimen MMRF_2597_1_BM_CD138pos (aliquot MMRF_2597_1_BM_CD138pos_T1_KHS5U_L12911) from MMRF case MMRF_2597, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 64.6 years (23,599 days).
Specimen MMRF_2597_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 537c3331-9415-4df3-a90d-655543cf68ac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2597_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2597_1_PB_Whole_C3_KHS5U_L12912; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bfce954f-d4cd-4ed9-9649-a292989bd64e

The open-access MAF lists 140 somatic variants for this specimen: 63 protein-altering or splice-affecting, 14 silent, 63 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, 3'UTR 32, Intron 16, Silent 14, 5'UTR 7, RNA 4, Frame Shift Del 4, 3'Flank 3, Frame Shift Ins 2, 5'Flank 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 17/44 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as rs1057519725, COSV55498939; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- ACTR3 | c.976A>G p.T326A | Missense Mutation (SNP) | VAF 95/252 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.837); catalogued as rs111973011; called by muse, mutect2, varscan2
- CLCN1 | c.2017G>T p.A673S | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated (0.39); PolyPhen benign (0.09); catalogued as rs200385034; called by muse, mutect2, varscan2
- DDX24 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 172/189 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58212911; called by muse, mutect2, varscan2
- DNAH2 | c.2032G>A p.V678I | Missense Mutation (SNP) | VAF 63/126 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.779); catalogued as rs753205736, COSV66727989; called by muse, mutect2, varscan2
- EPHA5 | c.1798G>A p.E600K | Missense Mutation (SNP) | VAF 69/73 reads (95%) | SIFT tolerated (0.92); PolyPhen benign (0.007); catalogued as rs151302542; called by muse, mutect2, varscan2
- FAM71A | c.571G>T p.D191Y | Missense Mutation (SNP) | VAF 144/224 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV54235404; called by muse, mutect2, varscan2
- FPR1 | c.665G>A p.G222E | Missense Mutation (SNP) | VAF 71/261 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59053012; called by muse, mutect2, varscan2
- IGHV2-70 | c.261G>T p.R87S | Missense Mutation (SNP) | VAF 125/196 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as rs371189824; called by muse, varscan2
- IGKJ4 | c.31A>G p.I11V | Missense Mutation (SNP) | VAF 41/115 reads (36%) | PolyPhen benign (0.003); catalogued as rs139461207; called by muse, varscan2
- IGLV3-1 | c.335G>T p.S112I | Missense Mutation (SNP) | VAF 142/154 reads (92%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); catalogued as rs374018767; called by muse, varscan2
- KARS1 | c.958C>T p.R320C | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.554); catalogued as COSV56691619; called by muse, mutect2, varscan2
- KIAA0586 | c.4162A>G p.M1388V (on ENST00000619416 / NM_001244190.2; = p.M1327V on NM_014749.5) | Missense Mutation (SNP) | VAF 90/244 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs890327400; called by muse, mutect2, varscan2
- LAMA1 | c.3235T>G p.L1079V | Missense Mutation (SNP) | VAF 94/208 reads (45%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.519); catalogued as COSV101058210; called by muse, mutect2, varscan2
- LAMB4 | c.2803G>A p.D935N | Missense Mutation (SNP) | VAF 112/239 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.258); catalogued as rs1256945011, COSV52713107; called by muse, mutect2, varscan2
- LRP2 | c.2455C>T p.R819C | Missense Mutation (SNP) | VAF 112/260 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs749942746, COSV55543681; called by muse, mutect2
- MAGEL2 | c.1669G>A p.A557T | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated, low confidence (0.15); catalogued as rs1175737367; called by muse, mutect2, varscan2
- PRC1 | c.272_274del p.E91del | In Frame Del (DEL) | VAF 54/188 reads (29%) | catalogued as rs770340123; called by pindel, varscan2
- PRKD3 | c.2605C>T p.H869Y | Missense Mutation (SNP) | VAF 65/136 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.027); catalogued as rs1023735330; called by muse, mutect2, varscan2
- SLC27A2 | c.524A>G p.D175G | Missense Mutation (SNP) | VAF 11/322 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as COSV51062112; called by muse, mutect2
- SLC2A3 | c.932C>T p.A311V | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.93); PolyPhen probably damaging (0.941); catalogued as rs777935518; called by muse, mutect2, varscan2
- TOGARAM1 | c.3932G>A p.R1311H | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs201399500, COSV63892585, COSV63895316; called by muse, mutect2, varscan2
- ZBTB8A | c.695G>A p.R232Q | Missense Mutation (SNP) | VAF 172/362 reads (48%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as rs369696394; called by muse, mutect2, varscan2
- AC006059.2 | c.977A>G p.D326G | Missense Mutation (SNP) | VAF 105/176 reads (60%) | SIFT tolerated (0.18); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- ANK2 | c.2499_2502del p.N834Yfs*5 | Frame Shift Del (DEL) | VAF 33/86 reads (38%) | called by mutect2, pindel, varscan2
- ANKFN1 | c.3676C>T p.R1226W (on ENST00000653862; = p.R1079W on NM_001365758.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/59 reads (88%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- AZU1 | c.253G>C p.D85H | Missense Mutation (SNP) | VAF 236/376 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- BAMBI | c.181T>A p.S61T | Missense Mutation (SNP) | VAF 133/302 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- BTBD3 | c.31T>C p.C11R | Missense Mutation (SNP) | VAF 102/222 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CACHD1 | c.579A>C p.E193D | Missense Mutation (SNP) | VAF 53/148 reads (36%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CPNE8 | c.970G>T p.A324S | Missense Mutation (SNP) | VAF 107/266 reads (40%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- DIS3 | c.2072A>C p.H691P | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DYNC2H1 | c.8534dup p.N2845Kfs*4 | Frame Shift Ins (INS) | VAF 18/36 reads (50%) | called by mutect2, varscan2
- ELP3 | c.650G>A p.G217E | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); called by muse, mutect2
- ERBB2 | c.2213T>A p.I738N | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- GOLGB1 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 100/224 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- HIPK1 | c.2384A>C p.N795T | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- HNRNPDL | c.65_66del p.L22Cfs*69 | Frame Shift Del (DEL) | VAF 12/28 reads (43%) | called by mutect2, varscan2
- ID3 | c.220A>C p.I74L | Missense Mutation (SNP) | VAF 119/252 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGHV1-69D | c.40G>C p.A14P | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); called by mutect2, varscan2
- IGKV1-5 | c.8T>A p.M3K | Missense Mutation (SNP) | VAF 81/84 reads (96%) | SIFT deleterious (0); PolyPhen benign (0.109); called by muse, varscan2
- IQGAP2 | c.422del p.N141Tfs*5 | Frame Shift Del (DEL) | VAF 42/102 reads (41%) | called by pindel, varscan2
- MAK16 | c.65G>A p.R22K | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MUC16 | c.16153C>T p.P5385S | Missense Mutation (SNP) | VAF 185/282 reads (66%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NME1-NME2 | c.773A>T p.H258L (on ENST00000555572; = p.H233L on NM_001018136.3) | Missense Mutation (SNP) | VAF 9/152 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- OR11H7 | c.799T>A p.S267T | Missense Mutation (SNP) | VAF 150/440 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- OR5D14 | c.91C>T p.L31F | Missense Mutation (SNP) | VAF 57/112 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- PCDH1 | c.2119G>A p.D707N | Missense Mutation (SNP) | VAF 58/188 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- POSTN | c.1477A>C p.K493Q | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.021); called by muse, mutect2
- PPFIA3 | c.1336_1356delinsT p.Q446Yfs*23 | Frame Shift Del (DEL) | VAF 50/202 reads (25%) | called by pindel, varscan2*
- PRR23A | c.106G>T p.G36C | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- RTL1 | c.2341G>A p.V781I | Missense Mutation (SNP) | VAF 88/101 reads (87%) | SIFT tolerated (0.37); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RYR3 | c.7237A>C p.N2413H (on ENST00000389232; = p.N2414H on NM_001036.6) | Missense Mutation (SNP) | VAF 54/173 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SALL3 | c.3471+2T>C p.X1157_splice | Splice Site (SNP) | VAF 43/98 reads (44%) | called by muse, mutect2, varscan2
- SCP2 | c.534dup p.E179* | Frame Shift Ins (INS) | VAF 32/88 reads (36%) | called by mutect2, pindel, varscan2
- TBX3 | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- THOC5 | c.1489G>A p.E497K | Missense Mutation (SNP) | VAF 129/341 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- TMEM87A | c.492T>G p.I164M | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- TRAV39 | c.318C>A p.F106L | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.58); PolyPhen benign (0.003); called by muse, mutect2
- UGCG | c.911G>A p.G304E | Missense Mutation (SNP) | VAF 97/285 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- ZNF2 | c.26G>T p.R9I | Missense Mutation (SNP) | VAF 201/381 reads (53%) | SIFT tolerated (0.15); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ZNF609 | c.3194G>A p.G1065D | Missense Mutation (SNP) | VAF 78/208 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- ZNF765 | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 32/524 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.184); called by muse, mutect2
- CNTRL | c.5106G>A p.L1702= | Silent (SNP) | VAF 80/242 reads (33%) | called by muse, mutect2, varscan2
- IGHV2-70 | c.168C>T p.S56= | Silent (SNP) | VAF 146/223 reads (65%) | catalogued as rs367953381; called by muse, varscan2
- IGHV2-70 | c.115C>T p.L39= | Silent (SNP) | VAF 47/145 reads (32%) | catalogued as rs186634824; called by muse, varscan2
- IGKV1-5 | c.324T>C p.Y108= | Silent (SNP) | VAF 28/30 reads (93%) | catalogued as rs11546103; called by muse, mutect2
- ITGA5 | c.2242C>A p.R748= | Silent (SNP) | VAF 68/137 reads (50%) | called by muse, mutect2, varscan2
- OR8H3 | c.450G>A p.V150= | Silent (SNP) | VAF 111/271 reads (41%) | catalogued as rs1357709756; called by muse, mutect2, varscan2
- PCDHA2 | c.1446G>A p.A482= | Silent (SNP) | VAF 19/88 reads (22%) | called by muse, mutect2, varscan2
- POU3F3 | c.924C>T p.H308= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as COSV100796898; called by muse, mutect2, varscan2
- SELP | c.1164G>A p.P388= | Silent (SNP) | VAF 52/161 reads (32%) | catalogued as rs145714766; called by muse, mutect2, varscan2
- SI | c.2049A>G p.K683= | Silent (SNP) | VAF 62/197 reads (31%) | called by muse, mutect2, varscan2
- TERB2 | c.102C>T p.A34= | Silent (SNP) | VAF 50/189 reads (26%) | catalogued as rs1488733137; called by muse, mutect2, varscan2
- TMEM132D | c.2208A>G p.T736= | Silent (SNP) | VAF 40/80 reads (50%) | catalogued as rs145783957; called by muse, mutect2, varscan2
- UBL7 | c.858T>C p.S286= | Silent (SNP) | VAF 12/30 reads (40%) | called by muse, mutect2, varscan2
- XCL2 | c.117A>G p.R39= | Silent (SNP) | VAF 55/66 reads (83%) | called by muse, mutect2, varscan2
- ABCC13 | n.659del | RNA (DEL) | VAF 26/58 reads (45%) | catalogued as rs763905102; called by mutect2, varscan2
- ACTB | c.-27-230C>T | Intron (SNP) | VAF 26/36 reads (72%) | called by muse, mutect2, varscan2
- ARRDC3 | c.*987T>C | 3'UTR (SNP) | VAF 16/79 reads (20%) | called by muse, mutect2, varscan2
- BMP6 | c.*1132T>G | 3'UTR (SNP) | VAF 22/66 reads (33%) | called by muse, mutect2, varscan2
- C1orf189 | c.*124G>A | 3'UTR (SNP) | VAF 101/155 reads (65%) | called by muse, mutect2, varscan2
- CCDC117 | c.*1860T>C | 3'UTR (SNP) | VAF 19/124 reads (15%) | called by muse, mutect2, varscan2
- CLSTN2 | c.*254A>C | 3'UTR (SNP) | VAF 87/230 reads (38%) | catalogued as rs999284160; called by muse, mutect2, varscan2
- CMTM6 | c.*2346dup | 3'UTR (INS) | VAF 16/70 reads (23%) | called by mutect2, varscan2
- CNKSR2 | c.*1125C>A | 3'UTR (SNP) | VAF 28/29 reads (97%) | called by muse, mutect2, varscan2
- COL13A1 | c.1882-125G>A | Intron (SNP) | VAF 29/51 reads (57%) | catalogued as rs1240778787; called by muse, mutect2, varscan2
- CTNNAL1 | c.1835+1554G>T | Intron (SNP) | VAF 107/383 reads (28%) | called by muse, mutect2, varscan2
- DACH2 | c.1751-690T>A | Intron (SNP) | VAF 7/50 reads (14%) | called by muse, mutect2, varscan2
- DCDC2 | c.*350T>G | 3'UTR (SNP) | VAF 90/138 reads (65%) | called by muse, mutect2, varscan2
- DENND1B | c.*3148T>C | 3'UTR (SNP) | VAF 37/59 reads (63%) | called by muse, mutect2, varscan2
- EFCC1 | c.*151C>T | 3'UTR (SNP) | VAF 59/216 reads (27%) | called by muse, mutect2, varscan2
- EGR1 | c.-100A>T | 5'UTR (SNP) | VAF 12/41 reads (29%) | called by muse, mutect2, varscan2
- EMILIN1 | c.*69C>T | 3'UTR (SNP) | VAF 6/12 reads (50%) | catalogued as rs1160968903; called by muse, mutect2, varscan2
- EPHB6 | c.1866-15C>G | Intron (SNP) | VAF 14/28 reads (50%) | catalogued as rs752338310; called by muse, varscan2
- FAM160B1 | c.*2066T>C | 3'UTR (SNP) | VAF 34/60 reads (57%) | called by muse, mutect2, varscan2
- FAM20B | c.*4087T>C | 3'UTR (SNP) | VAF 8/134 reads (6%) | called by muse, mutect2
- FUNDC2P2 | n.81C>T | RNA (SNP) | VAF 40/91 reads (44%) | called by muse, mutect2, varscan2
- GLRX2 | c.-8C>T | 5'UTR (SNP) | VAF 60/91 reads (66%) | catalogued as rs569607521; called by muse, mutect2, varscan2
- GM2A | c.*342T>G | 3'UTR (SNP) | VAF 24/104 reads (23%) | called by muse, mutect2, varscan2
- KCND3 | chr1:111775616 A>C | 3'Flank (SNP) | VAF 45/95 reads (47%) | called by muse, mutect2, varscan2
- KLHL1 | c.*930A>C | 3'UTR (SNP) | VAF 34/39 reads (87%) | called by muse, mutect2, varscan2
- KLHL1 | c.*929A>G | 3'UTR (SNP) | VAF 34/39 reads (87%) | called by muse, mutect2, varscan2
- LRRC2 | chr3:46517479 C>T | 3'Flank (SNP) | VAF 42/134 reads (31%) | catalogued as rs1236814373; called by muse, mutect2, varscan2
- LRRTM4 | c.-111G>A | 5'UTR (SNP) | VAF 83/182 reads (46%) | called by muse, mutect2, varscan2
- MTMR3 | c.671+61G>A | Intron (SNP) | VAF 3/22 reads (14%) | called by muse, mutect2
- N4BP2 | c.*679T>A | 3'UTR (SNP) | VAF 31/80 reads (39%) | called by muse, mutect2, varscan2
- NACC2 | c.*3473C>T | 3'UTR (SNP) | VAF 59/203 reads (29%) | catalogued as rs977624679; called by muse, mutect2, varscan2
- OTOF | c.*475G>A | 3'UTR (SNP) | VAF 39/93 reads (42%) | catalogued as rs1000952769; called by muse, mutect2, varscan2
- PCSK6 | c.2180+15G>A | Intron (SNP) | VAF 55/173 reads (32%) | catalogued as rs377128336; called by muse, mutect2, varscan2
- PFKP | c.621-385G>A | Intron (SNP) | VAF 31/73 reads (42%) | catalogued as rs756732461; called by muse, mutect2, varscan2
- PIGQ | c.942+107C>T | Intron (SNP) | VAF 36/70 reads (51%) | called by muse, mutect2
- PLA2R1 | c.-95C>T | 5'UTR (SNP) | VAF 21/48 reads (44%) | called by muse, mutect2, varscan2
- PLCB4 | c.*348A>G | 3'UTR (SNP) | VAF 44/90 reads (49%) | catalogued as rs1050502552; called by muse, mutect2, varscan2
- PLEKHG3 | chr14:64745658 A>G | 3'Flank (SNP) | VAF 39/117 reads (33%) | called by muse, mutect2, varscan2
- PRKACB | c.765+2229A>C | Intron (SNP) | VAF 27/60 reads (45%) | called by muse, mutect2, varscan2
- PXYLP1 | c.80-5394A>C | Intron (SNP) | VAF 29/90 reads (32%) | called by muse, mutect2, varscan2
- QKI | c.*1077A>C | 3'UTR (SNP) | VAF 34/113 reads (30%) | called by muse, mutect2, varscan2
- RAI14 | c.*1287G>C | 3'UTR (SNP) | VAF 25/76 reads (33%) | called by muse, mutect2, varscan2
- RFX4 | c.-106T>C | 5'UTR (SNP) | VAF 18/36 reads (50%) | called by muse, mutect2, varscan2
- RFX7 | c.-35G>A | 5'UTR (SNP) | VAF 88/317 reads (28%) | called by muse, mutect2, varscan2
- RNASE4 | c.-17-26C>A | Intron (SNP) | VAF 239/782 reads (31%) | catalogued as rs1566605740; called by muse, mutect2, varscan2
- RPL13AP7 | n.442C>T | RNA (SNP) | VAF 74/133 reads (56%) | catalogued as rs1240619291; called by muse, mutect2, varscan2
- RPS6KA3 | c.*2749T>C | 3'UTR (SNP) | VAF 46/49 reads (94%) | called by muse, mutect2, varscan2
- RYBP | c.*1498C>T | 3'UTR (SNP) | VAF 30/87 reads (34%) | called by muse, mutect2, varscan2
- SERAC1 | c.*424A>G | 3'UTR (SNP) | VAF 48/155 reads (31%) | called by muse, mutect2, varscan2
- SF3B1 | c.*174C>G | 3'UTR (SNP) | VAF 41/88 reads (47%) | called by muse, mutect2, varscan2
- SLC3A2 | chr11:62855685 C>T | 5'Flank (SNP) | VAF 10/25 reads (40%) | catalogued as rs746063079; called by muse, mutect2, varscan2
- STOML1 | c.133+386G>T | Intron (SNP) | VAF 21/80 reads (26%) | called by muse, mutect2, varscan2
- SUDS3 | c.*3128G>A | 3'UTR (SNP) | VAF 37/90 reads (41%) | called by muse, mutect2, varscan2
- SULT1E1 | c.*320del | 3'UTR (DEL) | VAF 6/8 reads (75%) | catalogued as rs976550394; called by mutect2, varscan2
- TEAD1 | c.330+21T>G | Intron (SNP) | VAF 72/167 reads (43%) | called by muse, mutect2, varscan2
- TMEM132B | c.*548C>T | 3'UTR (SNP) | VAF 41/92 reads (45%) | called by muse, mutect2, varscan2
- TTC23 | c.*1624G>T | 3'UTR (SNP) | VAF 30/51 reads (59%) | called by muse, mutect2, varscan2
- TTC32 | c.149+73T>C | Intron (SNP) | VAF 30/80 reads (38%) | called by muse, mutect2, varscan2
- UBE2S | c.-51G>A | 5'UTR (SNP) | VAF 14/55 reads (25%) | called by muse, mutect2, varscan2
- XIST | n.8005G>A | RNA (SNP) | VAF 28/32 reads (88%) | called by muse, mutect2, varscan2
- ZHX3 | c.*499G>A | 3'UTR (SNP) | VAF 64/148 reads (43%) | called by muse, mutect2, varscan2
- ZNF280D | c.381+1871T>G | Intron (SNP) | VAF 16/69 reads (23%) | called by muse, mutect2, varscan2
- ZNF746 | c.*1185G>A | 3'UTR (SNP) | VAF 39/73 reads (53%) | catalogued as rs1563245850; called by muse, mutect2, varscan2
